Somatic mutation profile of tumor specimen TCGA-D3-A8GR-06A (aliquot TCGA-D3-A8GR-06A-11D-A372-08) from TCGA case TCGA-D3-A8GR, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.0 years (23,747 days).
Specimen TCGA-D3-A8GR-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0600d93-1921-4f20-97e8-9d46c0c3570d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GR-10A (Blood Derived Normal), aliquot TCGA-D3-A8GR-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51cea836-7ea9-4a04-9c46-a56d09038b16

The open-access MAF lists 456 somatic variants for this specimen: 303 protein-altering or splice-affecting, 144 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 273, Silent 144, Nonsense Mutation 18, Splice Region 5, Intron 4, Frame Shift Del 3, Splice Site 3, 3'UTR 2, 5'UTR 1, RNA 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 205/278 reads (74%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCD4 | c.1547T>A p.V516E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); catalogued as COSV100084528; called by muse, mutect2, varscan2
- ABI3BP | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99428380; called by muse, mutect2, varscan2
- ACSS3 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as rs776097345, COSV54091174; called by muse, mutect2, varscan2
- ADAD1 | c.653A>T p.N218I | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV99636204; called by muse, mutect2, varscan2
- ADAM29 | c.711T>G p.D237E | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as COSV100822227; called by muse, mutect2, varscan2
- ADAM30 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1280658470, COSV101023966; called by muse, mutect2, varscan2
- ADAMTS9 | c.1743A>C p.E581D | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99900049, COSV99900106; called by muse, mutect2, varscan2
- ADGRF2 | c.311G>A p.R104K (on ENST00000296862 / NM_001368115.2; = p.R36K on NM_153839.7) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV99731701; called by muse, mutect2, varscan2
- ADGRV1 | c.24G>A p.G8= | Splice Region (SNP) | VAF 19/42 reads (45%) | catalogued as rs374852466, COSV67979256; called by muse, mutect2, varscan2
- ADIPOR1 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 67/75 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV100579648; called by muse, mutect2, varscan2
- AFAP1L2 | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100412957; called by muse, mutect2, varscan2
- AMBRA1 | c.323C>G p.S108* | Nonsense Mutation (SNP) | VAF 35/61 reads (57%) | catalogued as rs1171805665, COSV100095232; called by muse, mutect2, varscan2
- ANK3 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186719801, COSV99782045; called by muse, mutect2
- ANKRD12 | c.4625C>G p.T1542R | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV100042007; called by muse, mutect2, varscan2
- APOB | c.9406C>T p.R3136C | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs72653102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBR | c.3013C>T p.R1005W (on ENST00000431282; = p.R1014W on NM_018690.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754995250, COSV100112898; called by muse, mutect2, varscan2
- ARHGEF5 | c.2579G>C p.G860A | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99283136, COSV99283154; called by muse, mutect2
- ARID2 | c.3809C>T p.S1270F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100536959; called by muse, mutect2, varscan2
- ARIH1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV101158856; called by muse, mutect2, varscan2
- ARMCX2 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV100168270; called by muse, mutect2, varscan2
- ARMS2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.07); catalogued as COSV101600755; called by muse, mutect2, varscan2
- ASTN2 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100530154; called by muse, mutect2, varscan2
- ATG9B | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as rs969713819, COSV99874950; called by muse, mutect2
- BANK1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.051); catalogued as rs757599561, COSV100536775; called by muse, mutect2
- BIRC6 | c.10227T>A p.S3409R | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV101428782; called by muse, mutect2, varscan2
- BMP3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV51083460, COSV51085207; called by muse, mutect2
- BMPR1A | c.848T>C p.M283T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100923705; called by muse, mutect2, varscan2
- C1QTNF7 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV99765479; called by muse, mutect2, varscan2
- C2orf16 | c.5465A>G p.H1822R | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100820981; called by muse, mutect2, varscan2
- C6 | c.2021C>T p.T674I | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV54711052, COSV54720684; called by muse, mutect2, varscan2
- CA10 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99564864; called by muse, mutect2, varscan2
- CACNA1H | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373764821, CM032207; called by mutect2, varscan2
- CACNA2D3 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as COSV55568290; called by muse, mutect2, varscan2
- CADM2 | c.466G>A p.D156N (on ENST00000407528 / NM_001167674.2; = p.D158N on NM_153184.4) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV67407439; called by muse, mutect2, varscan2
- CALN1 | c.554G>A p.R185K (on ENST00000329008 / NM_001017440.3; = p.R227K on NM_031468.4) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs1321661961, COSV100209035, COSV61123923; called by muse, mutect2, varscan2
- CAMK1G | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99151965; called by muse, mutect2, varscan2
- CAND2 | c.1255G>A p.E419K (on ENST00000456430 / NM_001162499.2; = p.E326K on NM_012298.3) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV55992209, COSV99929679; called by muse, mutect2, varscan2
- CBLN2 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1464991471, COSV99504610; called by muse, mutect2, varscan2
- CCDC106 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100454434; called by muse, mutect2, varscan2
- CD244 | c.1048C>T p.P350S (on ENST00000368033 / NM_001166663.2; = p.P345S on NM_016382.4) | Missense Mutation (SNP) | VAF 127/189 reads (67%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs772313052, COSV99627387; called by muse, mutect2, varscan2
- CDC42BPB | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV100775591; called by muse, mutect2, varscan2
- CEMIP | c.3760A>T p.N1254Y | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99587225; called by muse, mutect2, varscan2
- CERKL | c.1528G>A p.E510K (on ENST00000339098 / NM_001030311.2; = p.E484K on NM_201548.5) | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.328); catalogued as rs139183162, COSV100184135; called by muse, mutect2, varscan2
- CGN | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 36/50 reads (72%) | catalogued as COSV99642763; called by muse, mutect2, varscan2
- CHP2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs769222851, COSV100270262; called by muse, mutect2, varscan2
- CIB2 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as rs1054728914, COSV51949758, COSV99363451; called by muse, mutect2, varscan2
- CLEC3A | c.370C>T p.Q124* (on ENST00000651443; = p.Q115* on NM_005752.6) | Nonsense Mutation (SNP) | VAF 50/106 reads (47%) | catalogued as rs141056312, COSV99077161; called by muse, mutect2, varscan2
- CLIC5 | c.597G>A p.M199I (on ENST00000185206 / NM_001370649.1; = p.M40I on NM_016929.5) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV99485297; called by muse, mutect2, varscan2
- CLSTN1 | c.1294C>T p.R432C (on ENST00000377298 / NM_001009566.3; = p.R422C on NM_014944.4) | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs368470193; called by muse, mutect2, varscan2
- CNBD1 | c.1202C>A p.S401Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101582192; called by muse, mutect2, varscan2
- COL24A1 | c.4052G>A p.G1351D | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100993937; called by muse, mutect2, varscan2
- COPA | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253097566, COSV54107149; called by muse, mutect2, varscan2
- CPED1 | c.2938G>A p.G980R | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121429; called by muse, mutect2, varscan2
- CPXCR1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV52160939; called by muse, mutect2
- CPXM2 | c.917A>T p.N306I | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99583237; called by muse, mutect2, varscan2
- CRYGB | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV99650022; called by muse, mutect2, varscan2
- CSMD1 | c.3443G>A p.R1148Q (on ENST00000520002; = p.R1147Q on NM_033225.6) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs766089311, COSV59289215; called by muse, mutect2, varscan2
- DAAM1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs751940752, COSV100658640; called by muse, mutect2, varscan2
- DDB1 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 62/87 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1487985200, COSV57103466; called by muse, mutect2, varscan2
- DHX57 | c.4078A>T p.K1360* | Nonsense Mutation (SNP) | VAF 37/90 reads (41%) | catalogued as COSV99769920; called by muse, mutect2, varscan2
- DIO3 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63773286; called by muse, mutect2, varscan2
- DMRT3 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 43/51 reads (84%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as rs778993459, COSV51902952; called by muse, mutect2, varscan2
- DMXL1 | c.7270T>C p.F2424L | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1395435865, COSV100224889; called by muse, mutect2, varscan2
- DNAH2 | c.2441G>A p.G814D | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV101209569; called by muse, mutect2, varscan2
- DNAH5 | c.3943G>A p.E1315K | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs753397685, COSV54219463; called by muse, varscan2
- DNAH7 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as rs766259116, COSV56768023; called by muse, mutect2, varscan2
- DNAH8 | c.6226C>T p.P2076S | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100547065, COSV104403221; called by muse, mutect2, varscan2
- DNAJC9 | c.277C>G p.Q93E | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs758227759, COSV99654946; called by muse, mutect2, varscan2
- DOCK4 | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as rs1413854018, COSV70244428; called by muse, mutect2, varscan2
- DOCK9 | c.2965C>T p.P989S (on ENST00000376460 / NM_001366676.2; = p.P990S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV100240858; called by muse, mutect2, varscan2
- DSC1 | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99938226; called by muse, mutect2, varscan2
- DSG4 | c.2735G>A p.G912D | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs746385171, COSV100356377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1I2 | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370576278; called by muse, mutect2, varscan2
- ECM1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 85/135 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV100682252; called by muse, mutect2, varscan2
- ELMO2 | c.569T>G p.L190R | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); catalogued as COSV99282007; called by muse, mutect2, varscan2
- EPB41L4A | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); catalogued as COSV99814046; called by muse, mutect2, varscan2
- ERICH3 | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.095); catalogued as COSV100445548; called by muse, mutect2, varscan2
- EVI2B | c.23T>C p.L8S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV100445641; called by muse, mutect2, varscan2
- EXPH5 | c.2732C>T p.P911L | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT tolerated (0.42); PolyPhen benign (0.065); catalogued as COSV99762127; called by muse, mutect2, varscan2
- EZH2 | c.1368G>T p.R456S (on ENST00000460911 / NM_001203247.2; = p.R461S on NM_004456.5) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs886062080, COSV100236637; called by muse, mutect2, varscan2
- F5 | c.2702C>T p.P901L | Missense Mutation (SNP) | VAF 151/237 reads (64%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100889219; called by muse, mutect2, varscan2
- FAAH2 | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV66513265; called by muse, mutect2, varscan2
- FAM126B | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99628213; called by muse, mutect2, varscan2
- FAM170A | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 96/238 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58924482; called by muse, mutect2, varscan2
- FAR1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 68/79 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199977186, COSV100701519, COSV100701650; called by muse, mutect2, varscan2
- FASN | c.4711C>T p.L1571F | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100147164, COSV100148273; called by muse, mutect2, varscan2
- FAT3 | c.13369C>T p.H4457Y | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.689); catalogued as COSV53116996; called by muse, mutect2
- FGFR2 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as rs1564913750, COSV100337144; called by muse, mutect2, varscan2
- FILIP1 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 98/255 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV52726579; called by muse, mutect2, varscan2
- FN1 | c.6979-1G>A p.X2327_splice (on ENST00000359671 / NM_001365524.2; = p.X2296_splice on NM_002026.4) | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100118143; called by muse, mutect2, varscan2
- FNDC7 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 234/323 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54752432; called by muse, mutect2, varscan2
- FOLH1 | c.1374A>C p.G458= | Splice Region (SNP) | VAF 34/44 reads (77%) | catalogued as COSV99923843; called by muse, mutect2, varscan2
- FOXK1 | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.375); catalogued as rs1172870281, COSV61064853; called by muse, mutect2, varscan2
- FOXK2 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV100081926; called by muse, mutect2, varscan2
- FRMPD4 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV101043940; called by muse, mutect2, varscan2
- FRS3 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs1408899482, COSV99443120; called by muse, mutect2, varscan2
- GALNT14 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV100205495; called by muse, mutect2, varscan2
- GHRH | c.189-1G>A p.X63_splice | Splice Site (SNP) | VAF 50/149 reads (34%) | catalogued as COSV52903035, COSV99411222; called by muse, mutect2, varscan2
- GPAM | c.823T>G p.F275V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100788402; called by muse, mutect2, varscan2
- GPER1 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204139972, COSV99867363; called by muse, mutect2, varscan2
- GPRASP1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV100851069; called by muse, mutect2, varscan2
- GPRASP1 | c.3448A>C p.K1150Q | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV100851070; called by muse, mutect2, varscan2
- GRIK2 | c.1320A>G p.E440= | Splice Region (SNP) | VAF 27/70 reads (39%) | catalogued as rs1426600470, COSV100029067; called by muse, mutect2, varscan2
- GRM4 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV100946841; called by muse, mutect2, varscan2
- GRM4 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs866300355, COSV100946098; called by muse, mutect2, varscan2
- GSG1 | c.435G>A p.G145= (on ENST00000651961 / NM_001080555.4; = p.G109= on NM_031289.5) | Splice Region (SNP) | VAF 20/47 reads (43%) | catalogued as rs751973707, COSV100189498; called by muse, mutect2, varscan2
- GUCY2D | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1413127106, COSV99644105; called by muse, mutect2, varscan2
- H6PD | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV101072520; called by muse, mutect2, varscan2
- HACD1 | c.559A>T p.T187S | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as COSV100778514; called by muse, mutect2, varscan2
- HOXD12 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1159299631, COSV101184338; called by muse, mutect2, varscan2
- HSPA1L | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); catalogued as COSV100989455, COSV100989461; called by muse, mutect2, varscan2
- HTATSF1 | c.1688G>A p.R563K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99511887; called by muse, mutect2, varscan2
- HUWE1 | c.9917C>T p.S3306L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV99474056; called by muse, mutect2, varscan2
- IGDCC3 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV100031486; called by muse, mutect2, varscan2
- IKBKB | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100645824; called by muse, mutect2, varscan2
- IKZF3 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV53105237; called by muse, mutect2, varscan2
- IL7R | c.750T>A p.F250L | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV100286606; called by muse, mutect2, varscan2
- IL7R | c.751T>G p.F251V | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV100286607; called by muse, mutect2, varscan2
- IQCH | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100246307; called by muse, mutect2, varscan2
- IRF8 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250694242, COSV51897551; called by muse, mutect2, varscan2
- IRX5 | c.532A>C p.T178P | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100315975; called by muse, mutect2, varscan2
- ITGAL | c.497G>A p.S166N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100776339; called by muse, mutect2, varscan2
- ITIH2 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV100623401; called by muse, mutect2, varscan2
- ITLN2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1461204773, COSV63537456; called by muse, mutect2, varscan2
- JARID2 | c.929C>T p.T310I | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1228491036, COSV100522346; called by muse, mutect2, varscan2
- KATNA1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 70/89 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV100167979; called by muse, mutect2, varscan2
- KCNB1 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 104/219 reads (47%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.836); catalogued as rs770677266, COSV65566515; called by muse, mutect2, varscan2
- KCNN3 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV99679148; called by muse, mutect2, varscan2
- KCTD11 | c.619G>A p.E207K (on ENST00000333751 / NM_001363642.1; = p.E168K on NM_001002914.2) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as COSV99341952; called by muse, mutect2, varscan2
- KDM5A | c.1033T>G p.C345G | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101239046; called by muse, mutect2, varscan2
- KIAA1109 | c.418A>C p.N140H | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99174497; called by muse, mutect2, varscan2
- KLF8 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100808275, COSV100808408; called by muse, mutect2, varscan2
- KLHL4 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64139282, COSV64140562, COSV64142481; called by muse, mutect2, varscan2
- KMT2D | c.8832C>G p.N2944K | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as COSV99985454; called by muse, mutect2, varscan2
- KRT1 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs751464239, COSV99358976; called by muse, mutect2, varscan2
- LAMA2 | c.183A>T p.K61N | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.31); catalogued as COSV101370796, COSV70342618; called by muse, mutect2, varscan2
- LHCGR | c.877T>C p.S293P | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.732); catalogued as rs1331596023, COSV99684162; called by muse, mutect2
- LIFR | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV54696824; called by muse, mutect2, varscan2
- LIMK2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.396); catalogued as COSV100058954; called by muse, mutect2, varscan2
- LPAR4 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV70913528; called by muse, mutect2, varscan2
- LRIT2 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.369); catalogued as rs151197977; called by muse, mutect2, varscan2
- LRRC8C | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100968410; called by muse, mutect2, varscan2
- LSMEM2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV57112990; called by muse, mutect2
- LTN1 | c.2354-1G>A p.X785_splice | Splice Site (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100798180; called by muse, mutect2, varscan2
- LZTS2 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.474); catalogued as COSV100932212, COSV100932267; called by muse, mutect2, varscan2
- MAGEA10 | c.184T>C p.S62P | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.617); catalogued as rs1442829230, COSV99726899; called by muse, mutect2, varscan2
- MAGEE1 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100819510, COSV63909518; called by muse, mutect2, varscan2
- MAP3K10 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV53424878, COSV99454177; called by muse, mutect2, varscan2
- MARK3 | c.1838C>T p.T613I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1306752107, COSV99358738; called by muse, mutect2, varscan2
- MCF2 | c.901A>G p.N301D | Missense Mutation (SNP) | VAF 102/260 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100645103; called by muse, mutect2, varscan2
- MUC16 | c.27482C>T p.S9161F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.133); catalogued as COSV101201401; called by muse, mutect2, varscan2
- MUC16 | c.25492G>A p.E8498K | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1477168068, COSV101200229, COSV101201403; called by muse, mutect2, varscan2
- MUC16 | c.15952C>T p.P5318S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.011); catalogued as rs1568855126, COSV101201404; called by muse, mutect2, varscan2
- MUC16 | c.11975T>C p.V3992A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as COSV101201405; called by muse, mutect2, varscan2
- MUC20 | c.1924A>G p.T642A | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as COSV100291479; called by muse, mutect2, varscan2
- MXRA5 | c.3209G>A p.G1070E | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54235560; called by muse, mutect2, varscan2
- MYBPC1 | c.1448G>A p.G483E (on ENST00000550270 / NM_206820.2; = p.G508E on NM_002465.4) | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV62252714; called by muse, mutect2, varscan2
- MYH13 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs1201130211, COSV99355319; called by muse, mutect2, varscan2
- MYH6 | c.5159C>T p.S1720F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100676959; called by muse, mutect2, varscan2
- MYLK3 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV67365947; called by muse, mutect2, varscan2
- MYO9A | c.7099C>T p.L2367F | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100614226; called by muse, mutect2, varscan2
- MYOM3 | c.4297G>A p.E1433K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV58390519; called by muse, mutect2, varscan2
- NAA25 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99927976; called by muse, mutect2, varscan2
- NCOR2 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100657819; called by muse, mutect2, varscan2
- NDST4 | c.2191C>T p.P731S | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV99997721, COSV99998153; called by muse, mutect2, varscan2
- NELL2 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.154); catalogued as COSV100420678; called by muse, mutect2, varscan2
- NEXMIF | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99280927, COSV99281763; called by muse, mutect2, varscan2
- NLGN2 | c.2036C>T p.T679I | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100081249; called by muse, mutect2
- NLRP1 | c.3804G>A p.M1268I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV52560941, COSV52566767; called by muse, mutect2, varscan2
- NLRP11 | c.1445G>A p.R482K | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV100789807, COSV64086535; called by muse, mutect2, varscan2
- NRP2 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); catalogued as COSV99785533; called by muse, mutect2, varscan2
- NUP88 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1249723221, COSV56707524; called by muse, mutect2, varscan2
- OR10J3 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs868734843, COSV59953696, COSV59955976; called by muse, mutect2, varscan2
- OR11A1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1457527436, COSV101010738; called by muse, mutect2, varscan2
- OR1C1 | c.212T>G p.I71S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101376272; called by muse, mutect2, varscan2
- OR51I1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100972018; called by muse, mutect2, varscan2
- OSMR | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV99953667; called by muse, mutect2, varscan2
- OTOL1 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs546746940, COSV100020225; called by muse, mutect2, varscan2
- OTOL1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100020227; called by muse, mutect2, varscan2
- PABPC3 | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 47/87 reads (54%) | catalogued as rs1253433057, COSV99880002; called by muse, varscan2
- PAGE5 | c.56G>C p.R19T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99215843; called by muse, mutect2, varscan2
- PAK5 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs921511471, COSV100781651, COSV62019893, COSV62023459; called by muse, mutect2, varscan2
- PAPPA2 | c.4019C>T p.S1340L | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100868567; called by muse, mutect2, varscan2
- PCDHGA1 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.158); catalogued as rs1426384785, COSV100966064; called by muse, mutect2, varscan2
- PCDHGB5 | c.1952C>A p.S651Y | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53920423; called by muse, mutect2, varscan2
- PDCD11 | c.3875T>G p.V1292G | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs1050164482, COSV100874412; called by muse, mutect2, varscan2
- PDE10A | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1477904642, COSV100605661; called by muse, mutect2, varscan2
- PDPR | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV55353888; called by muse, mutect2, varscan2
- PIAS3 | c.1500G>T p.M500I | Missense Mutation (SNP) | VAF 68/306 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100566851; called by muse, mutect2, varscan2
- PKD1L1 | c.8225A>T p.K2742I | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99221248; called by muse, mutect2, varscan2
- PKHD1 | c.2556G>A p.W852* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100584423; called by muse, mutect2, varscan2
- PKHD1L1 | c.10537C>T p.P3513S | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV101006758; called by muse, mutect2, varscan2
- PKN3 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.519); catalogued as COSV99403901; called by muse, mutect2, varscan2
- PLCB4 | c.2982G>A p.M994I | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs753931051, COSV53798516; called by muse, mutect2, varscan2
- PLCH1 | c.5018C>T p.S1673F (on ENST00000340059 / NM_001130960.2; = p.S1665F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as rs745529770, COSV100397874, COSV100398122; called by muse, mutect2, varscan2
- PLIN1 | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs1015496903, COSV100261694; called by muse, mutect2, varscan2
- PLOD3 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as rs376124107, COSV99778276; called by muse, mutect2, varscan2
- PLRG1 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776693518, COSV100123238; called by muse, mutect2, varscan2
- PLXNA3 | c.2032C>T p.H678Y | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV100860226; called by muse, mutect2
- POLE2 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.303); catalogued as COSV99364799, COSV99364976; called by muse, mutect2, varscan2
- PPFIA2 | c.3633G>A p.M1211I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as COSV61028986; called by muse, mutect2, varscan2
- PPP1R3F | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as rs782810558, COSV99278993; called by muse, mutect2, varscan2
- PRIMPOL | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775404693, COSV59248099; called by muse, mutect2, varscan2
- PRKAA2 | c.894A>T p.E298D | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100983061; called by muse, mutect2, varscan2
- PRKD3 | c.894A>T p.Q298H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99306696; called by muse, mutect2, varscan2
- PRPH2 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100028240; called by muse, mutect2, varscan2
- PSG11 | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 131/377 reads (35%) | catalogued as COSV100106139; called by muse, mutect2, varscan2
- PSTPIP2 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1463540987, COSV68957715; called by muse, mutect2, varscan2
- PTPN22 | c.2225C>T p.P742L (on ENST00000359785 / NM_001193431.2; = p.P687L on NM_012411.5) | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV63084302; called by muse, mutect2, varscan2
- RABGAP1L | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52300722, COSV99273790; called by muse, mutect2, varscan2
- RALGAPB | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99485323; called by muse, mutect2, varscan2
- RAPGEF3 | c.2528G>A p.R843K (on ENST00000389212; = p.R801K on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as COSV50232651, COSV99406784; called by muse, mutect2, varscan2
- RAPGEF5 | c.974A>T p.K325I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV100687788; called by muse, mutect2, varscan2
- REEP1 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV99383303; called by muse, mutect2, varscan2
- REV1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99301232, COSV99301434; called by muse, mutect2, varscan2
- RGS8 | c.167C>T p.S56F (on ENST00000367556 / NM_001369564.2; = p.S74F on NM_033345.3) | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51116018; called by muse, mutect2, varscan2
- RHAG | c.1019T>G p.V340G | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.195); catalogued as COSV100006839; called by muse, mutect2, varscan2
- RHPN1 | c.1850G>A p.R617K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1214242289, COSV100000877; called by muse, mutect2
- RNF14 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100641293; called by muse, mutect2, varscan2
- ROS1 | c.6793G>A p.E2265K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV100876919; called by muse, mutect2, varscan2
- ROS1 | c.6374T>C p.V2125A | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100877663; called by muse, mutect2, varscan2
- ROS1 | c.4525G>A p.E1509K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1489503636, COSV63853731; called by muse, mutect2, varscan2
- RPL38 | c.186dup p.G63Rfs*14 | Frame Shift Ins (INS) | VAF 18/71 reads (25%) | catalogued as rs758386023; called by mutect2, pindel, varscan2
- S100A9 | c.214A>C p.K72Q | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV100907216; called by muse, mutect2, varscan2
- SAMD9L | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 80/147 reads (54%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV59086325; called by muse, mutect2, varscan2
- SCN10A | c.5345G>A p.R1782Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs267599796, COSV71860696; called by muse, mutect2, varscan2
- SCN11A | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 27/79 reads (34%) | catalogued as rs749301699, COSV56568211; called by muse, mutect2, varscan2
- SCN7A | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV101313068; called by muse, mutect2, varscan2
- SCO1 | c.592C>G p.P198A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1265107604, COSV99703617; called by muse, mutect2, varscan2
- SDK1 | c.5864C>T p.P1955L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as rs749986515, COSV67371756; called by muse, mutect2, varscan2
- SEMA3F | c.189C>G p.D63E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99137891; called by muse, mutect2, varscan2
- SERPINI2 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.993); catalogued as rs1331526626, COSV99248364; called by muse, mutect2, varscan2
- SETBP1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99954747; called by muse, mutect2, varscan2
- SFPQ | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100599510, COSV61758332; called by muse, mutect2, varscan2
- SH3GL3 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100197423; called by muse, mutect2, varscan2
- SHROOM2 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV101099024; called by muse, mutect2, varscan2
- SLAMF6 | c.677T>C p.M226T | Missense Mutation (SNP) | VAF 89/127 reads (70%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV100924942; called by muse, mutect2, varscan2
- SLAMF9 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV100928187; called by muse, mutect2, varscan2
- SLC5A6 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.006); catalogued as COSV100143547; called by muse, mutect2, varscan2
- SLC6A12 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100675211; called by muse, mutect2
- SLC6A12 | c.1810G>A p.G604R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1233666290, COSV100675212; called by muse, mutect2
- SLC7A2 | c.365C>T p.S122L (on ENST00000494857 / NM_001370338.1; = p.S162L on NM_003046.6) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777770011, COSV50260346, COSV99135105; called by muse, mutect2, varscan2
- SLC8A3 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776362; called by muse, mutect2, varscan2
- SLITRK4 | c.1755T>A p.N585K | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100567505; called by muse, mutect2, varscan2
- SMARCA4 | c.3569C>T p.A1190V | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1196923492, COSV100759091; called by muse, mutect2, varscan2
- SMC1A | c.1931C>T p.T644I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447660; called by muse, mutect2, varscan2
- SNURF | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100578586, COSV57597777; called by muse, mutect2, varscan2
- SPANXN1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as COSV65122342, COSV65123446; called by muse, mutect2, varscan2
- SPTA1 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs767319344, COSV100935504, COSV63757453; called by muse, mutect2, varscan2
- SPTBN5 | c.5486G>A p.R1829Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.114); catalogued as rs775437209, COSV58023190; called by muse, mutect2
- SREK1IP1 | c.15T>C p.G5= | Splice Region (SNP) | VAF 16/55 reads (29%) | catalogued as COSV101536192; called by muse, mutect2, varscan2
- STK38L | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1235703958, COSV101198821; called by muse, mutect2, varscan2
- SUCNR1 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 38/56 reads (68%) | catalogued as rs748612865, COSV62912530; called by muse, mutect2, varscan2
- SYT16 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV70860752; called by muse, mutect2, varscan2
- TBC1D32 | c.3298C>T p.L1100F | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99251145; called by muse, mutect2, varscan2
- TCF25 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139621812; called by muse, mutect2, varscan2
- TCN2 | c.547G>T p.V183L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.136); catalogued as COSV99308788; called by muse, mutect2, varscan2
- TEAD1 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 122/159 reads (77%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV100532823; called by muse, mutect2, varscan2
- TEAD1 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 123/160 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV100532825; called by muse, mutect2, varscan2
- TECTA | c.5810A>G p.Y1937C | Missense Mutation (SNP) | VAF 67/93 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV99881398; called by muse, mutect2, varscan2
- TEX13B | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100258494; called by muse, mutect2, varscan2
- THOC2 | c.4162T>A p.S1388T | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99834085; called by muse, varscan2
- THOC2 | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.339); catalogued as COSV99834087; called by muse, varscan2
- TLR4 | c.2391G>A p.W797* (on ENST00000355622 / NM_138554.5; = p.W757* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 24/46 reads (52%) | catalogued as COSV62922642; called by muse, mutect2, varscan2
- TMC7 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.017); catalogued as COSV100432788, COSV58582217; called by muse, mutect2, varscan2
- TNFSF11 | c.286A>T p.N96Y | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99520689; called by muse, mutect2, varscan2
- TNR | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 82/126 reads (65%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV54869230, COSV54922353; called by muse, mutect2, varscan2
- TNR | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 148/219 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.589); catalogued as rs1001407974, COSV54877336; called by muse, mutect2, varscan2
- TNS4 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99564122; called by muse, mutect2, varscan2
- TPO | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0.096); catalogued as COSV100221956, COSV61106332; called by muse, mutect2, varscan2
- TPRG1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs774658153, COSV100800839; called by muse, mutect2, varscan2
- TRAPPC8 | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99351904; called by muse, mutect2, varscan2
- TRPM6 | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV62503032; called by muse, mutect2, varscan2
- TSPYL5 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs1300016645, COSV100439105; called by muse, mutect2, varscan2
- TTN | c.89920G>A p.E29974K (on ENST00000591111; = p.E22550K on NM_003319.4) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | PolyPhen benign (0.178); catalogued as rs72648254, COSV100627817; called by muse, mutect2, varscan2
- TTN | c.19721A>T p.K6574M (on ENST00000591111; = p.K5647M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | PolyPhen probably damaging (0.999); catalogued as COSV100627826; called by muse, mutect2, varscan2
- TUBA1A | c.572C>G p.T191S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV99853834; called by muse, mutect2, varscan2
- UBQLN3 | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 73/90 reads (81%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV100293949, COSV61165551; called by muse, mutect2, varscan2
- UNC79 | c.2312C>T p.P771L (on ENST00000393151 / NM_001346218.2; = p.P594L on NM_020818.5) | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs751135621, COSV99829212; called by muse, mutect2, varscan2
- USP25 | c.1193T>C p.V398A | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV99584464; called by muse, mutect2, varscan2
- VCAN | c.5530C>T p.P1844S | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV99427161; called by muse, mutect2, varscan2
- ZBTB33 | c.724A>G p.N242D | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100434313; called by muse, mutect2, varscan2
- ZBTB40 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 44/111 reads (40%) | catalogued as COSV100989095; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 94/177 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs139577861; called by muse, mutect2, varscan2
- ZDBF2 | c.4063G>T p.E1355* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100985472; called by muse, mutect2, varscan2
- ZFHX4 | c.7433C>T p.S2478F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs867940806, COSV51494451; called by muse, mutect2, varscan2
- ZHX2 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs1278235645, COSV100073833; called by muse, mutect2, varscan2
- ZNF208 | c.3655C>T p.H1219Y | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV68101248; called by muse, mutect2, varscan2
- ZNF331 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.239); catalogued as rs769874224, COSV53478915; called by muse, mutect2, varscan2
- ZNF407 | c.3160T>G p.Y1054D | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996641; called by muse, mutect2, varscan2
- ZNF664 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544574; called by muse, mutect2, varscan2
- ZNF711 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1199153672, COSV52153693; called by muse, mutect2, varscan2
- ZNF836 | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100441203; called by muse, mutect2, varscan2
- ZNF98 | c.1415A>C p.N472T | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV100757603; called by muse, mutect2, varscan2
- ZNF99 | c.1794T>G p.C598W | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101233947; called by muse, mutect2, varscan2
- DHX57 | c.2260_2291del p.K754Afs*7 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel
- ENPEP | c.1866_1882del p.D622Efs*5 | Frame Shift Del (DEL) | VAF 35/103 reads (34%) | called by mutect2, pindel, varscan2
- KMT2A | c.11474del p.K3825Rfs*31 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | called by pindel, varscan2
- KMT2A | c.11475G>T p.K3825N | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, varscan2
- OR2T8 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.33); called by muse, mutect2
- PHF8 | c.287C>T p.S96F (on ENST00000357988 / NM_001184896.1; = p.S60F on NM_015107.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- SLC43A3 | c.126_130del p.Y42* | Nonsense Mutation (DEL) | VAF 13/29 reads (45%) | called by mutect2, pindel, varscan2
- ACTN4 | c.384C>T p.S128= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV53142698, COSV99400695; called by muse, mutect2, varscan2
- ADAMTS6 | c.2784G>A p.R928= | Silent (SNP) | VAF 63/156 reads (40%) | catalogued as rs1461796557, COSV58685278; called by muse, mutect2, varscan2
- ADAP1 | c.786G>A p.T262= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as rs139452042, COSV56210435; called by muse, mutect2, varscan2
- ADH7 | c.111G>A p.E37= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs1182493297, COSV99265327, COSV99265439; called by muse, mutect2, varscan2
- AGBL5 | c.2439G>A p.R813= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1230778696, COSV100789565; called by muse, mutect2, varscan2
- AKAP6 | c.4995G>A p.K1665= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99028585, COSV99804084; called by muse, mutect2, varscan2
- ALDH3A1 | c.765G>A p.S255= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs991274538, COSV99856025; called by muse, mutect2, varscan2
- ANKS3 | c.531T>C p.A177= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100423261; called by muse, mutect2, varscan2
- AOC1 | c.1029A>T p.G343= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV100710954; called by muse, mutect2, varscan2
- ARHGAP10 | c.1572C>T p.S524= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV100331718; called by muse, mutect2, varscan2
- AVPR1B | c.120C>A p.V40= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as rs1553290616, COSV100899444; called by muse, mutect2, varscan2
- BBS2 | c.1131C>T p.I377= | Silent (SNP) | VAF 54/164 reads (33%) | catalogued as COSV55326282; called by muse, mutect2, varscan2
- BTBD17 | c.138C>T p.S46= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1251873411, COSV100945398; called by muse, mutect2, varscan2
- CACNA1D | c.321C>T p.F107= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV55460052, COSV99859845; called by muse, mutect2, varscan2
- CDH7 | c.1653G>A p.R551= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100543141; called by muse, mutect2, varscan2
- CEBPZ | c.2037T>C p.A679= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as rs745424156, COSV99305414; called by muse, mutect2, varscan2
- CGAS | c.936T>A p.I312= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100943692; called by muse, mutect2, varscan2
- CIB2 | c.309C>T p.P103= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV99363452; called by muse, mutect2, varscan2
- CLSTN1 | c.1293C>T p.F431= (on ENST00000377298 / NM_001009566.3; = p.F421= on NM_014944.4) | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as COSV100790745; called by muse, mutect2, varscan2
- COG7 | c.2178C>A p.G726= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100207783; called by muse, mutect2, varscan2
- COL21A1 | c.1995G>A p.G665= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99780062; called by muse, varscan2
- CPNE9 | c.1305C>A p.V435= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as rs758252039, COSV99808459; called by muse, mutect2, varscan2
- CSMD2 | c.1263C>T p.F421= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as rs867435567, COSV53876622; called by muse, mutect2, varscan2
- CSNK1E | c.648C>T p.L216= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV100725091; called by muse, mutect2, varscan2
- CYP1A2 | c.117G>A p.L39= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as rs767672496, COSV100673937; called by muse, mutect2, varscan2
- CYP4F8 | c.39G>A p.P13= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs773376604, COSV100358026, COSV57854536; called by muse, mutect2
- DIP2B | c.3180C>T p.I1060= | Silent (SNP) | VAF 48/117 reads (41%) | catalogued as rs747998083, COSV56582858; called by muse, mutect2, varscan2
- DMD | c.8682G>A p.E2894= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as rs779231646, COSV100629113; called by muse, mutect2, varscan2
- DSCAM | c.793C>T p.L265= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs1208948275, COSV101261416; called by muse, mutect2, varscan2
- ECM1 | c.288C>T p.L96= | Silent (SNP) | VAF 83/134 reads (62%) | catalogued as COSV100681990, COSV100682249; called by muse, mutect2, varscan2
- EPB41L5 | c.984C>T p.P328= | Silent (SNP) | VAF 49/163 reads (30%) | catalogued as rs142943979; called by muse, mutect2, varscan2
- EPHA10 | c.2502C>T p.I834= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV100361675; called by muse, mutect2, varscan2
- ESPL1 | c.4266C>T p.S1422= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs1232230539, COSV99229726; called by muse, mutect2, varscan2
- FASN | c.4710C>T p.S1570= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs753346824, COSV100148277; called by muse, mutect2, varscan2
- FBXO11 | c.366C>A p.A122= (on ENST00000403359 / NM_001190274.2; = p.A38= on NM_025133.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV100319933; called by muse, mutect2, varscan2
- FGF6 | c.612C>T p.F204= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV57403697; called by muse, mutect2, varscan2
- FLG | c.4893G>A p.R1631= | Silent (SNP) | VAF 112/497 reads (23%) | catalogued as rs376924209; called by muse, mutect2, varscan2
- FLT3 | c.333C>T p.S111= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99610056; called by muse, mutect2, varscan2
- FMN1 | c.3234C>T p.F1078= (on ENST00000616417 / NM_001277313.2; = p.F855= on NM_001103184.4) | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs865986556, COSV100569259; called by muse, mutect2, varscan2
- FN1 | c.3762G>A p.K1254= | Silent (SNP) | VAF 61/148 reads (41%) | catalogued as COSV100118144; called by muse, mutect2, varscan2
- FRS3 | c.390C>T p.L130= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs1210550720, COSV52484945; called by muse, mutect2, varscan2
- FUT10 | c.585C>T p.L195= | Silent (SNP) | VAF 67/133 reads (50%) | catalogued as COSV100161720; called by muse, mutect2, varscan2
- GASK1B | c.268C>T p.L90= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV99648080; called by muse, mutect2, varscan2
- GPATCH8 | c.4491C>T p.P1497= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs566581403, COSV100132837; called by muse, mutect2, varscan2
- GPR45 | c.792G>A p.K264= | Silent (SNP) | VAF 50/159 reads (31%) | catalogued as rs1273491996, COSV51523883; called by muse, mutect2, varscan2
- GRIK3 | c.1962G>A p.T654= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs777065201, COSV100902284, COSV66145034; called by muse, mutect2, varscan2
- GUCY2C | c.2937C>T p.F979= | Silent (SNP) | VAF 57/145 reads (39%) | catalogued as rs867327497, COSV99663409; called by muse, mutect2, varscan2
- HERC4 | c.1758C>T p.F586= | Silent (SNP) | VAF 53/132 reads (40%) | catalogued as rs146594352; called by muse, mutect2, varscan2
- HOXD13 | c.939G>A p.T313= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs150319624; called by muse, mutect2, varscan2
- HTR1E | c.861G>A p.R287= | Silent (SNP) | VAF 61/152 reads (40%) | catalogued as COSV100541278; called by muse, mutect2, varscan2
- IGFN1 | c.2139G>A p.R713= (on ENST00000295591 / NM_001367841.1; = p.R3170= on NM_001164586.2) | Silent (SNP) | VAF 82/92 reads (89%) | catalogued as COSV99813483; called by muse, mutect2, varscan2
- IGHV3-30 | c.109C>T p.L37= | Silent (SNP) | VAF 46/333 reads (14%) | called by muse, mutect2, varscan2
- IGKV2D-24 | c.306G>A p.R102= | Silent (SNP) | VAF 54/162 reads (33%) | catalogued as rs755791400; called by muse, mutect2, varscan2
- IMPG1 | c.222C>T p.F74= | Silent (SNP) | VAF 44/95 reads (46%) | catalogued as rs780783100, COSV64053839; called by muse, mutect2, varscan2
- JPH3 | c.1260C>T p.S420= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV99413950; called by muse, mutect2, varscan2
- KCNH5 | c.441G>A p.T147= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as rs753750382, COSV59752889; called by muse, mutect2, varscan2
- KCNN1 | c.1101G>A p.R367= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99716303; called by muse, mutect2, varscan2
- KEL | c.612C>T p.F204= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as rs1194784105, COSV62334021; called by muse, mutect2, varscan2
- KIR3DL2 | c.858C>T p.T286= | Silent (SNP) | VAF 104/255 reads (41%) | catalogued as COSV99552331; called by muse, mutect2, varscan2
- KRT4 | c.651G>A p.Q217= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV99543189; called by muse, mutect2, varscan2
- LMNTD1 | c.1011C>T p.P337= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV99280278; called by muse, mutect2, varscan2
- MFSD11 | c.1245C>T p.L415= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs776839329, COSV100334127, COSV100334243; called by muse, mutect2, varscan2
- MRPL4 | c.453T>C p.V151= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99460332; called by muse, mutect2, varscan2
- MX1 | c.801C>T p.L267= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs768910580, COSV55819221; called by muse, mutect2, varscan2
- MYH13 | c.360C>T p.G120= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV99355323; called by muse, mutect2, varscan2
- MYH2 | c.1389G>A p.L463= | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as COSV99820869; called by muse, mutect2, varscan2
- MYH7 | c.1689C>T p.F563= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs1273710361, COSV62518518; called by muse, mutect2, varscan2
- MYL1 | c.189C>T p.D63= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100498765; called by muse, mutect2, varscan2
- MYO15A | c.9879C>T p.F3293= | Silent (SNP) | VAF 65/137 reads (47%) | catalogued as rs867374525, COSV99234282; called by muse, mutect2, varscan2
- NCBP2L | c.399G>A p.R133= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100966524; called by muse, mutect2, varscan2
- NLGN4X | c.79C>T p.L27= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV99323693; called by muse, mutect2, varscan2
- NLRP11 | c.819C>T p.F273= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV100789698; called by muse, mutect2, varscan2
- NOBOX | c.1326C>T p.L442= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1295512022, COSV99779666; called by muse, varscan2
- NYAP2 | c.408G>A p.R136= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV99798298; called by muse, mutect2, varscan2
- OR13C4 | c.342C>T p.L114= | Silent (SNP) | VAF 63/87 reads (72%) | catalogued as rs1207691866, COSV52925884; called by muse, mutect2, varscan2
- OR1C1 | c.462C>T p.L154= | Silent (SNP) | VAF 37/49 reads (76%) | catalogued as COSV101376271; called by muse, mutect2, varscan2
- OR1I1 | c.525C>T p.S175= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV99264902; called by muse, mutect2, varscan2
- OR2G3 | c.417G>A p.R139= | Silent (SNP) | VAF 173/201 reads (86%) | catalogued as COSV100180746; called by muse, mutect2, varscan2
- OR2L3 | c.456G>A p.S152= | Silent (SNP) | VAF 272/334 reads (81%) | catalogued as rs781220819, COSV100741938, COSV63455019; called by muse, varscan2
- OR4A47 | c.12G>A p.R4= | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as COSV71444964; called by muse, mutect2, varscan2
- OR51G2 | c.849C>T p.F283= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as COSV58991839; called by muse, mutect2, varscan2
- OR5P2 | c.48C>T p.I16= | Silent (SNP) | VAF 42/52 reads (81%) | catalogued as COSV100271358, COSV100271434; called by muse, mutect2, varscan2
- OSMR | c.1842G>A p.E614= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV99953669; called by muse, mutect2, varscan2
- PABPC3 | c.1323C>T p.F441= | Silent (SNP) | VAF 48/88 reads (55%) | catalogued as COSV99879999; called by muse, varscan2
- PCARE | c.198G>A p.R66= | Silent (SNP) | VAF 49/109 reads (45%) | catalogued as rs1484485102, COSV59053493; called by muse, mutect2, varscan2
- PCDHB16 | c.2313C>T p.I771= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV99502779; called by muse, mutect2, varscan2
- PCDHGB5 | c.1953C>T p.S651= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs375308173; called by muse, mutect2, varscan2
- PDE6C | c.447G>A p.T149= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs547315589, COSV65115432; called by muse, mutect2, varscan2
- PDE9A | c.387G>A p.E129= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs144139094; called by muse, mutect2, varscan2
- PI4KA | c.552C>T p.I184= | Silent (SNP) | VAF 59/143 reads (41%) | catalogued as rs372013185; called by muse, mutect2, varscan2
- PKHD1L1 | c.5094C>T p.F1698= | Silent (SNP) | VAF 58/130 reads (45%) | catalogued as COSV65744776; called by muse, mutect2, varscan2
- PKP2 | c.2262G>A p.R754= | Silent (SNP) | VAF 56/159 reads (35%) | catalogued as COSV50742487; called by muse, mutect2, varscan2
- PLEKHG3 | c.1476C>T p.H492= (on ENST00000394691; = p.H548= on NM_001308147.2) | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as COSV99907050; called by muse, mutect2, varscan2
- PRAMEF4 | c.816C>T p.L272= | Silent (SNP) | VAF 100/443 reads (23%) | catalogued as COSV99340177; called by muse, mutect2, varscan2
- PRPF40B | c.729G>A p.L243= (on ENST00000380281; = p.L237= on NM_012272.3) | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99980122; called by muse, mutect2, varscan2
- PWWP3A | c.420C>T p.P140= (on ENST00000627377; = p.P139= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV100262242; called by muse, mutect2, varscan2
- RASGRP4 | c.1467G>A p.E489= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV99385144; called by muse, mutect2, varscan2
- RASL12 | c.483C>T p.F161= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1304738010, COSV54982822; called by muse, mutect2, varscan2
- RBM19 | c.714A>G p.E238= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as COSV99926745; called by muse, mutect2, varscan2
- RBM47 | c.1653G>A p.T551= (on ENST00000295971 / NM_001098634.2; = p.T482= on NM_019027.4) | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV99921574; called by muse, mutect2, varscan2
- RFPL1 | c.663G>A p.R221= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV100585897; called by muse, mutect2, varscan2
- RHBG | c.510C>T p.L170= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as rs1428736449, COSV99660035; called by muse, mutect2, varscan2
- RTL5 | c.312G>A p.L104= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs1212200239, COSV101030317; called by muse, mutect2, varscan2
- RUFY4 | c.1587C>T p.G529= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV100723212; called by muse, mutect2, varscan2
- SATB2 | c.291G>C p.V97= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV99612487; called by muse, mutect2, varscan2
- SEPTIN5 | c.828G>A p.A276= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100820462; called by muse, mutect2, varscan2
- SGSM1 | c.2745C>T p.S915= (on ENST00000400359 / NM_001039948.4; = p.S854= on NM_133454.3) | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV100771889; called by muse, mutect2, varscan2
- SHISA5 | c.123C>T p.P41= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs114793780, COSV99604725; called by muse, mutect2, varscan2
- SLC25A23 | c.1041C>T p.P347= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99902592; called by muse, mutect2, varscan2
- SLC28A1 | c.411G>A p.R137= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as rs372865550; called by muse, mutect2, varscan2
- SLC2A14 | c.1164T>C p.F388= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100533998; called by muse, mutect2, varscan2
- SLC9A2 | c.825C>T p.I275= | Silent (SNP) | VAF 78/184 reads (42%) | catalogued as rs1431914223, COSV52131232; called by muse, mutect2, varscan2
- SNED1 | c.1686C>T p.S562= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as rs1186726334, COSV100123355; called by muse, mutect2, varscan2
- SNRNP70 | c.651C>T p.S217= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs766055520, COSV55505506; called by muse, mutect2, varscan2
- SPATC1 | c.483C>T p.S161= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs1554755510, COSV101085277; called by muse, mutect2, varscan2
- STYXL2 | c.2751C>T p.V917= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV99609828; called by muse, mutect2, varscan2
- SYT7 | c.954G>A p.E318= | Silent (SNP) | VAF 50/72 reads (69%) | catalogued as rs1156293590, COSV99802114; called by muse, mutect2, varscan2
- TACC2 | c.1092G>A p.K364= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV57772450; called by muse, mutect2, varscan2
- TANC1 | c.2497C>T p.L833= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs1311840297, COSV99715063; called by muse, mutect2, varscan2
- TBL3 | c.1023G>C p.R341= | Silent (SNP) | VAF 44/147 reads (30%) | catalogued as COSV100225060; called by muse, mutect2, varscan2
- TCL1B | c.108C>T p.V36= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs946147523, COSV61552015; called by muse, mutect2, varscan2
- TEP1 | c.972A>T p.R324= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV99403144; called by muse, mutect2, varscan2
- TMEM184A | c.559C>T p.L187= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV52474029, COSV99868751; called by muse, mutect2, varscan2
- TMPRSS3 | c.6G>A p.G2= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99368645; called by muse, mutect2, varscan2
- TNS4 | c.402C>T p.T134= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV99564120; called by muse, mutect2, varscan2
- TRAPPC8 | c.2040C>T p.G680= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV99351902; called by muse, mutect2, varscan2
- TRIB3 | c.810C>T p.F270= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1003885985, COSV99423988; called by muse, mutect2, varscan2
- TRIM38 | c.21C>T p.T7= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100837637; called by muse, mutect2, varscan2
- TRPM7 | c.2599C>T p.L867= | Silent (SNP) | VAF 51/101 reads (50%) | catalogued as COSV100540274; called by muse, mutect2, varscan2
- TSEN2 | c.1068C>A p.P356= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV99539366; called by muse, mutect2, varscan2
- TTN | c.81958C>T p.L27320= (on ENST00000591111; = p.L19896= on NM_003319.4) | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100627820; called by muse, mutect2, varscan2
- TTN | c.69843G>A p.R23281= (on ENST00000591111; = p.R15857= on NM_003319.4) | Silent (SNP) | VAF 57/132 reads (43%) | catalogued as COSV100627823; called by muse, mutect2, varscan2
- TTN | c.34113G>A p.E11371= (on ENST00000591111; = p.E10444= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100627824; called by mutect2, varscan2
- TTR | c.435C>T p.P145= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1333113934, COSV99379634; called by muse, mutect2
- TVP23B | c.471T>C p.V157= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV100314608, COSV57059178; called by muse, mutect2, varscan2
- UGT2B7 | c.1242A>G p.R414= | Silent (SNP) | VAF 68/177 reads (38%) | catalogued as rs753837836, COSV59444317; called by muse, mutect2, varscan2
- USP11 | c.1503C>T p.I501= (on ENST00000218348; = p.I458= on NM_001371072.1) | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs749581378, COSV99511143; called by muse, mutect2, varscan2
- UTP20 | c.2133C>T p.V711= | Silent (SNP) | VAF 47/112 reads (42%) | catalogued as rs1178124905, COSV99882458; called by muse, mutect2, varscan2
- VRTN | c.1116G>A p.E372= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99832468; called by muse, mutect2, varscan2
- ZBED6CL | c.306C>T p.V102= | Silent (SNP) | VAF 59/103 reads (57%) | catalogued as rs753595180, COSV59604782; called by muse, mutect2, varscan2
- ZDBF2 | c.4062G>A p.L1354= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100985467; called by muse, mutect2, varscan2
- ZNF385D | c.372G>A p.K124= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV55747575; called by muse, mutect2, varscan2
- ZNF99 | c.1983C>T p.S661= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV101233826; called by muse, mutect2, varscan2
- ZP1 | c.1539G>A p.L513= | Silent (SNP) | VAF 29/39 reads (74%) | catalogued as COSV99612795; called by muse, mutect2, varscan2
- CTDSP2 | c.412-350C>T | Intron (SNP) | VAF 32/72 reads (44%) | catalogued as COSV101143081; called by muse, mutect2, varscan2
- GCSH | chr16:81101169 G>A | 5'Flank (SNP) | VAF 44/75 reads (59%) | called by muse, mutect2, varscan2
- IFRD2 | c.-60C>T | 5'UTR (SNP) | VAF 7/27 reads (26%) | catalogued as COSV57112827; called by muse, mutect2, varscan2
- MIR548I1 | n.52G>A | RNA (SNP) | VAF 16/38 reads (42%) | catalogued as rs566890365; called by muse, mutect2, varscan2
- NACA | c.71-2839C>T | Intron (SNP) | VAF 23/43 reads (53%) | catalogued as rs1381221095, COSV100771605; called by muse, mutect2, varscan2
- NALCN | c.2193-5762G>A | Intron (SNP) | VAF 7/10 reads (70%) | catalogued as rs771478582, COSV99213186; called by muse, mutect2, varscan2
- NPR3 | c.*3093G>A | 3'UTR (SNP) | VAF 39/108 reads (36%) | catalogued as COSV99423782; called by muse, mutect2, varscan2
- PLXNA4 | c.1372-87024G>A | Intron (SNP) | VAF 28/43 reads (65%) | catalogued as rs191301122, COSV58107612; called by muse, mutect2, varscan2
- PRSS37 | c.*1G>A | 3'UTR (SNP) | VAF 47/82 reads (57%) | catalogued as COSV100633886; called by muse, mutect2, varscan2
